Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WN, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WN-01A (Primary Tumor).

ICD-O-3

Astrocytoma, grade III NOS
Date Brain, supratentorial
C71.0

9/10/13

Translation

diffuse astrocytic tumor with increased proliferation

IDH1 mutation

isolated 19q deletion (1p intact)

Diagnosis:

anaplastic astrocytoma WHO grade III

II/IA Discrepancy		☒
For Malignancy History		☒

Untranslated full
report is housed
at the BCR.

Source: NCI Genomic Data Commons file 48a646ee-dbaf-48a3-b90c-556705985dbb (TCGA-S9-A6WN.DF6F3A7F-700B-4AB7-8E0A-87F81AEB3C59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).